Somatic mutation profile of tumor specimen TARGET-30-PAUUHD-01A (aliquot TARGET-30-PAUUHD-01A-01D) from TARGET case TARGET-30-PAUUHD, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 5.1 years (1,857 days).
Specimen TARGET-30-PAUUHD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5512a77-12ba-4fa0-8071-50b4d657b9dc.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUUHD-10A (Blood Derived Normal), aliquot TARGET-30-PAUUHD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5030621b-78b1-47d6-9e65-8b5c3de6af81

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK | c.604G>T p.G202W | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57206676; called by muse, mutect2, varscan2
- HELB | c.2860A>C p.K954Q | Missense Mutation (SNP) | VAF 78/118 reads (66%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV56072829; called by muse, varscan2
- HELB | c.2885C>G p.P962R | Missense Mutation (SNP) | VAF 82/128 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as COSV56072836; called by muse, varscan2
- KMT2E | c.1560G>A p.M520I | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs143750087; called by muse, mutect2, varscan2
- FCGBP | c.9122G>T p.W3041L | Missense Mutation (SNP) | VAF 52/250 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- FGFR1 | c.1553-47G>T | Intron (SNP) | VAF 8/155 reads (5%) | called by muse, mutect2
